Somatic mutation profile of tumor specimen MP2PRT-PARXRZ-TMP1-A (aliquot MP2PRT-PARXRZ-TMP1-A-1-0-D-A80I-36) from MP2PRT case MP2PRT-PARXRZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.0 years (1,821 days).
Specimen MP2PRT-PARXRZ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 078ca63b-bd8e-4162-bd9f-b3a07e89894d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARXRZ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARXRZ-NB1-A-1-0-D-A80I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1362a9d3-ecf5-4da8-9643-a7d4a9da2790

The open-access MAF lists 26 somatic variants for this specimen: 21 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 3, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP8A2 | c.214C>G p.Q72E | Missense Mutation (SNP) | VAF 14/423 reads (3%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs1411547070; called by muse, mutect2
- DSCAML1 | c.980C>T p.P327L (on ENST00000321322; = p.P267L on NM_020693.4) | Missense Mutation (SNP) | VAF 33/675 reads (5%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); catalogued as rs763722217, COSV58397842, COSV58400217; called by muse, mutect2
- EID2 | c.517G>C p.E173Q | Missense Mutation (SNP) | VAF 43/387 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.696); catalogued as rs1468059012; called by muse, mutect2, varscan2
- HSD3B1 | c.529G>A p.G177S | Missense Mutation (SNP) | VAF 216/453 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs757135187; called by muse, mutect2, varscan2
- OR5K2 | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 184/487 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as rs373316744; called by muse, mutect2, varscan2
- PADI2 | c.1590G>T p.K530N | Missense Mutation (SNP) | VAF 40/294 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.491); catalogued as COSV104429070; called by mutect2, varscan2
- PTAR1 | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 14/434 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.068); catalogued as COSV100466687, COSV61208939; called by muse, mutect2
- SGSM2 | c.731G>A p.R244H | Missense Mutation (SNP) | VAF 52/640 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762725574, COSV52155745, COSV52159414; called by muse, mutect2
- ST6GAL2 | c.1481G>A p.R494H | Missense Mutation (SNP) | VAF 188/591 reads (32%) | PolyPhen benign (0.362); catalogued as rs757962368, COSV62418156; called by muse, mutect2
- VDR | c.472C>T p.R158C | Missense Mutation (SNP) | VAF 15/287 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.733); catalogued as CM117231, COSV57467145; called by muse, mutect2
- CAPN6 | c.1458C>G p.I486M | Missense Mutation (SNP) | VAF 47/497 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.142); called by muse, mutect2
- CCR3 | c.230C>T p.A77V | Missense Mutation (SNP) | VAF 16/400 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- DCAF8L2 | c.1796G>C p.G599A | Missense Mutation (SNP) | VAF 16/640 reads (3%) | SIFT tolerated (0.53); PolyPhen benign (0.033); called by muse, mutect2
- ESPN | c.4036G>T p.D1346Y | Missense Mutation (SNP) | VAF 18/424 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2
- LAMA2 | c.2201C>G p.S734C | Missense Mutation (SNP) | VAF 9/255 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- LMBRD2 | c.1323C>G p.I441M | Missense Mutation (SNP) | VAF 31/229 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR4P4 | c.310T>A p.F104I | Missense Mutation (SNP) | VAF 190/432 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- PCNT | c.1667C>G p.S556C | Missense Mutation (SNP) | VAF 27/300 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.005); called by muse, mutect2
- TCP11L2 | c.809C>G p.S270C | Missense Mutation (SNP) | VAF 93/263 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- TPR | c.4528G>A p.E1510K | Missense Mutation (SNP) | VAF 22/276 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.932); called by muse, mutect2
- TRIL | c.1921G>C p.E641Q | Missense Mutation (SNP) | VAF 21/686 reads (3%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.946); called by muse, mutect2
- IGKV1OR2-108 | chr2:113406872 TCACAGTGTTA>CCTAG | Silent (DEL) | VAF 67/83 reads (81%) | called by pindel, varscan2*
- MPPED1 | c.765C>A p.V255= | Silent (SNP) | VAF 15/436 reads (3%) | called by muse, mutect2
- UMPS | c.78C>T p.F26= | Silent (SNP) | VAF 17/596 reads (3%) | catalogued as COSV51736186; called by muse, mutect2
- DST | c.4297-4023G>A | Intron (SNP) | VAF 26/443 reads (6%) | catalogued as COSV55042876; called by muse, mutect2
- IRX5 | c.250-361C>G | Intron (SNP) | VAF 25/609 reads (4%) | called by muse, mutect2
